Somatic mutation profile of tumor specimen TARGET-30-PAVCLI-01A (aliquot TARGET-30-PAVCLI-01A-01D) from TARGET case TARGET-30-PAVCLI, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 11.3 years (4,112 days).
Specimen TARGET-30-PAVCLI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2b7d2b3f-8367-45d9-8127-cc25fa9a375f.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAVCLI-10A (Blood Derived Normal), aliquot TARGET-30-PAVCLI-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f22f101-3c4b-4afb-b375-7bb98fbd8fba

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABBR2 | c.2458C>A p.P820T | Missense Mutation (SNP) | VAF 30/207 reads (14%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV99411231; called by muse, mutect2, varscan2
- NOS1 | c.2119C>G p.P707A | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- TMPRSS13 | chr11:117901336 G>A | 3'Flank (SNP) | VAF 20/210 reads (10%) | called by muse, mutect2
